Gene-level copy-number profile of tumor specimen C3N-03933-03 from CPTAC case C3N-03933, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 70.2 years (25,635 days).
Specimen C3N-03933-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e24d285-1534-4a28-9d38-6588ee32e789.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03933-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,262 have no estimate.
https://portal.gdc.cancer.gov/files/1d5a69c2-dd6f-4596-a818-57fb0a33d9e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 1,494; copy number 2: 53,530; copy number 3: 3,052; copy number 4: 196; copy number 5: 18; copy number 6: 3; copy number 7: 5; copy number 8: 5; copy number 9: 26.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,094,461–66,094,546, 1 gene (within-gene range 0–2): RNU4-88P.
- chr1:118,712,999–118,713,678, 1 gene: AL139148.1.
- chr1:194,488,103–194,488,205, 1 gene: RNU6-983P.
- chr2:29,681,027–29,681,323, 1 gene (within-gene range 0–2): RN7SL516P.
- chr2:56,750,300–56,750,563, 1 gene: PPIAP63.
- chr2:140,234,737–140,234,923, 1 gene (within-gene range 0–2): AC092156.1.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr3:75,964,980–75,965,069, 1 gene (within-gene range 0–2): Y_RNA.
- chr4:27,262,506–27,267,254, 1 gene (within-gene range 0–2): AC024132.3.
- chr5:43,874,367–43,886,628, 1 gene: AC104119.1.
- chr7:110,215,891–110,216,380, 1 gene: AC073114.2.
- chr8:46,822,174–46,907,309, 6 genes (within-gene range 0–1): LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20.
- chr9:80,565,032–80,565,962, 1 gene: MTND2P9.
- chr10:85,193,421–85,197,958, 1 gene: LINC01519.
- chr10:108,940,969–108,941,310, 1 gene: RN7SKP278.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr11:54,682,877–54,693,359, 2 genes: OR4A8, OR4A7P.
- chr11:55,343,151–55,344,231, 1 gene: OR4A16.
- chr11:89,981,441–89,999,741, 2 genes: TRIM51EP, TRIM53AP.
- chr11:92,498,152–92,498,935, 1 gene (within-gene range 0–2): RPS3AP42.
- chr11:93,991,346–93,991,429, 1 gene: AP002795.1.
- chr12:91,050,491–91,058,024, 1 gene: KERA.
- chr13:75,136,154–75,136,940, 1 gene: SSR1P2.
- chr16:7,726,841–7,726,951, 1 gene: AC005774.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,355,669–39,655,531, 10 genes, copy number 5: SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8.
- chr9:60,914,407–60,964,196, 5 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,865,755–61,866,965, 1 gene, copy number 6: AL391987.4.
- chr9:64,369,394–64,413,142, 2 genes, copy number 6: ANKRD20A4P, RNU6-1193P.
- chr9:64,498,517–64,498,745, 1 gene, copy number 8: AL773524.1.
- chr9:67,832,765–68,300,035, 5 genes, copy number 5 (within-gene range 5–6): ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4.
- chr11:89,869,282–89,889,991, 3 genes, copy number 5: TRIM64B, AP005435.4, AP005435.2.
- chr15:22,178,107–22,202,734, 4 genes, copy number 8: IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3.
- chr21:7,744,962–8,454,792, 26 genes, copy number 9: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 1,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
